Somatic mutation profile of tumor specimen TCGA-DX-A7EF-01A (aliquot TCGA-DX-A7EF-01A-11D-A33E-09) from TCGA case TCGA-DX-A7EF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-A7EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c05e77e-4291-41a2-b5e1-d683345be570.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EF-10A (Blood Derived Normal), aliquot TCGA-DX-A7EF-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b2ad47e-fe81-4cf4-8332-1ac9605fb176

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 30, Silent 14, Splice Site 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6729+2C>A p.X2243_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100933167; called by muse, mutect2, varscan2
- ABCG5 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571359; called by muse, mutect2, varscan2
- ACSL3 | c.2117A>G p.K706R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100657991; called by muse, mutect2, varscan2
- AEBP2 | c.1449T>A p.D483E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.978); catalogued as COSV99857897; called by muse, mutect2, varscan2
- AHNAK | c.13134G>A p.M4378I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99948372; called by muse, mutect2, varscan2
- ALMS1 | c.11689G>A p.G3897S | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.811); catalogued as rs187887110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCT5 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as rs140095139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL19A1 | c.3182A>C p.K1061T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100506813; called by muse, mutect2, varscan2
- EIF2AK3 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs200171164, COSV57548474, COSV57553833; called by muse, mutect2, varscan2
- HOOK1 | c.1053G>C p.M351I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV100969162; called by muse, mutect2, varscan2
- KNDC1 | c.203G>C p.S68T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV100465522; called by muse, mutect2, varscan2
- MAP2K4 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796367; called by muse, mutect2, varscan2
- MYO3A | c.4157T>C p.V1386A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV99780482; called by muse, mutect2, varscan2
- NEXMIF | c.3058G>T p.D1020Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV50021603, COSV99281227, COSV99281597; called by muse, mutect2
- NOMO2 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100395731; called by muse, mutect2, varscan2
- NXPH3 | c.566C>A p.S189* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100165542, COSV60872520; called by muse, mutect2, varscan2
- OPN1SW | c.43A>C p.I15L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs200504235; called by muse, mutect2, varscan2
- PCDH7 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100688488; called by muse, mutect2, varscan2
- PHKA1 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263419, COSV100263541; called by mutect2, varscan2
- RHOV | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs774701533, COSV99592118; called by muse, mutect2, varscan2
- RRM2 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV100459726; called by muse, mutect2, varscan2
- SALL1 | c.1052C>A p.P351Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV51753393, COSV99175093; called by muse, mutect2, varscan2
- SEL1L2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99533494; called by muse, mutect2, varscan2
- TBC1D22B | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100996855; called by muse, mutect2, varscan2
- TMEM132A | c.2858G>A p.R953Q (on ENST00000453848 / NM_178031.3; = p.R954Q on NM_017870.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.398); catalogued as rs780314026, COSV50033586; called by muse, mutect2, varscan2
- TMEM211 | c.545C>A p.T182N (on ENST00000423535; = p.T111N on NM_001001663.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101236043; called by muse, mutect2, varscan2
- TRPC5 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV99461738; called by muse, mutect2, varscan2
- TSC1 | c.2843A>G p.Y948C | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs989183765, COSV100052097, COSV53766986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC39B | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99895620; called by muse, mutect2, varscan2
- ZNF790 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100764857; called by muse, mutect2, varscan2
- PTTG1IP | c.281_284del p.N94Mfs*4 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- SLC35F1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.216); called by muse, mutect2
- TUBGCP5 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- ZNF335 | c.3469_3471del p.T1157del | In Frame Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel
- ARHGDIB | c.577C>T p.L193= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99844387; called by muse, mutect2, varscan2
- CLVS1 | c.492G>A p.L164= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs779122829, COSV57975868; called by muse, mutect2
- DAPP1 | c.165C>T p.D55= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs554960188, COSV56450647; called by muse, mutect2, varscan2
- EDN1 | c.369C>T p.C123= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV101040423; called by muse, mutect2
- EPN3 | c.939G>A p.P313= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs769871618, COSV52139411; called by muse, mutect2, varscan2
- GRAP2 | c.141C>T p.P47= | Silent (SNP) | VAF 38/55 reads (69%) | catalogued as rs1456325805, COSV100703055; called by muse, mutect2, varscan2
- JUN | c.300C>T p.P100= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV100973455; called by muse, mutect2
- LAS1L | c.1608T>C p.Y536= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1390519004, COSV100408621; called by muse, mutect2
- LGALS3BP | c.1566C>T p.A522= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99431795; called by muse, mutect2, varscan2
- MET | c.99C>T p.S33= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs1363905218, COSV100577297; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLGN1 | c.1419G>A p.A473= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs200258151; called by muse, mutect2, varscan2
- OR5H14 | c.201T>A p.A67= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs759331938, COSV101454225; called by muse, mutect2, varscan2
- SYPL2 | c.267C>T p.I89= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100881562, COSV63995040; called by muse, mutect2, varscan2
- TRIP6 | c.864G>T p.G288= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as COSV99566770; called by muse, mutect2, varscan2
